Gene-level copy-number profile of tumor specimen TCGA-21-1077-01A from TCGA case TCGA-21-1077, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 64.4 years (23,523 days).
Specimen TCGA-21-1077-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.0f5b733a-eed0-4de3-b90b-11c32b02a5f9.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-21-1077-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d1f7dfcd-d30d-4b11-9de0-8d2bd8070173

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,451; copy number 2: 31,437; copy number 3: 15,712; copy number 4: 6,298; copy number 5: 2,711; copy number 6: 48; copy number 7: 311; copy number 8: 134; copy number 11: 460; copy number 16: 257.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-21-1077-01): tumor purity 0.34, ploidy 2.64, whole-genome doublings 1 (call status: maf_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,921 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:15,668,684–21,970,959, 97 genes, copy number 6–8 (broad region; genes not listed).
- chr2:48,809,340–49,419,013, 1 gene, copy number 5 (within-gene range 4–5): AC009975.1.
- chr2:48,962,157–67,825,562, 276 genes, copy number 5–8 (within-gene range 4–8) (broad region; genes not listed).
- chr3:74,262,568–75,085,237, 2 genes, copy number 5: CNTN3, NIPA2P2.
- chr3:142,724,034–198,222,513, 958 genes, copy number 7–16 (broad region; genes not listed).
- chr5:58,198–45,895,970, 710 genes, copy number 5 (broad region; genes not listed).
- chr8:27,311,482–28,083,936, 25 genes, copy number 5 (within-gene range 2–5): PTK2B, MIR6842, CHRNA2, EPHX2, GULOP, CLU, MIR6843, SCARA3, RNU6-1086P, AC013643.1, AC013643.3, MIR3622B, MIR3622A, AC013643.2, CCDC25, ESCO2, RNU6-1276P, PBK, AC104997.1, SCARA5, MIR4287, AC069113.1, AC069113.3, AC069113.2, NUGGC.
- chr8:35,235,475–35,796,550, 1 gene, copy number 5 (within-gene range 2–5): UNC5D.
- chr8:35,525,176–35,525,763, 1 gene, copy number 5: LSM12P1.
- chr8:46,028,804–49,820,944, 70 genes, copy number 5 (broad region; genes not listed).
- chr8:116,766,505–122,733,804, 62 genes, copy number 5–7 (within-gene range 2–7) (broad region; genes not listed).
- chr8:127,072,694–127,742,951, 12 genes, copy number 6 (within-gene range 4–6): CASC19, PRNCR1, AC020688.1, AC018714.2, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, AC108925.1, CASC11, MYC.
- chr15:82,010,212–101,933,350, 496 genes, copy number 5 (broad region; genes not listed).
- chr22:19,121,529–50,801,309, 1,210 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,449. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
